Somatic mutation profile of tumor specimen TCGA-L5-A8NH-01A (aliquot TCGA-L5-A8NH-01A-11D-A37C-09) from TCGA case TCGA-L5-A8NH, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 54.7 years (19,991 days).
Specimen TCGA-L5-A8NH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 425546a4-9b2b-42b5-be07-f1e7e78a01b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NH-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NH-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e0279f9-6348-43ae-91f5-cf8b11bf39a4

The open-access MAF lists 128 somatic variants for this specimen: 99 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 27, Frame Shift Ins 4, Intron 2, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 19/31 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AQP3 | c.533T>C p.I178T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763291383; called by muse, mutect2
- CACNA1D | c.3829G>A p.V1277I (on ENST00000350061 / NM_001128840.3; = p.V1297I on NM_000720.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1329352704, COSV55445896; called by muse, mutect2, varscan2
- CBLN4 | c.317dup p.T107Hfs*22 | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | catalogued as rs1474631237; called by mutect2, pindel, varscan2
- CCN4 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 70/92 reads (76%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.458); catalogued as rs760043627, COSV51530809; called by muse, mutect2, varscan2
- CD2 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.031); catalogued as rs373098399; called by muse, mutect2, varscan2
- CHRNG | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as rs375087506; called by muse, mutect2, varscan2
- CNGA1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs759487836, COSV62053254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP4 | c.3871A>G p.S1291G | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.15); catalogued as rs754006513; called by muse, mutect2, varscan2
- DNAH9 | c.12652G>A p.E4218K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1295435678; called by muse, mutect2, varscan2
- DPRX | c.510A>C p.Q170H | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV64949255; called by muse, mutect2, varscan2
- EDNRB | c.685T>G p.L229V (on ENST00000377211 / NM_001201397.1; = p.L139V on NM_000115.5) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs143042375; called by muse, mutect2, varscan2
- EPN1 | c.1384A>G p.T462A (on ENST00000270460 / NM_001321263.1; = p.T436A on NM_013333.3) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1303722798; called by muse, mutect2
- FMR1 | c.581C>G p.T194S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV54423184; called by muse, mutect2, varscan2
- GPA33 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); catalogued as rs201186970; called by muse, mutect2, varscan2
- GPR139 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV58503909; called by muse, mutect2, varscan2
- GRIK4 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs768347024, COSV70803463; called by muse, mutect2, varscan2
- GRN | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs1026683055; called by muse, mutect2, varscan2
- KCNH8 | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as rs768191040; called by muse, mutect2, varscan2
- KIAA0319 | c.1987G>A p.V663I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as rs772281560, COSV100985541; called by muse, mutect2, varscan2
- LRTM1 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs749421719, COSV55532842; called by muse, mutect2, varscan2
- MAP7D1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201457297, COSV60215723; called by muse, mutect2, varscan2
- NCOA2 | c.2881G>C p.V961L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.171); catalogued as rs1375931753; called by muse, mutect2, varscan2
- OR10Q1 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs747579093; called by mutect2, varscan2
- PCDHA12 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as rs782436615; called by muse, mutect2
- PEG3 | c.422A>T p.D141V | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV55629604; called by muse, mutect2, varscan2
- PFN4 | c.308C>A p.T103N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57531005; called by muse, mutect2, varscan2
- PRDM8 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.944); catalogued as COSV60203116; called by muse, varscan2
- PRMT1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV55864796; called by muse, mutect2
- PRRC2C | c.884G>A p.R295H (on ENST00000367742; = p.R293H on NM_015172.4) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1413237512, COSV58907252; called by muse, mutect2, varscan2
- SEPTIN1 | c.586C>T p.R196W (on ENST00000321367; = p.R149W on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs765085320, COSV58441354; called by muse, mutect2, varscan2
- SEPTIN1 | c.266_268del p.I89del (on ENST00000321367; = p.I42del on NM_052838.6 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 6/39 reads (15%) | catalogued as rs754490038; called by pindel, varscan2
- SNAP91 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99536628; called by muse, mutect2, varscan2
- SPATA31D1 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.113); catalogued as rs778459117, COSV61199267; called by muse, mutect2, varscan2
- SRGAP3 | c.802-1G>A p.X268_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100841440; called by muse, mutect2, varscan2
- SUSD2 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs749892017; called by muse, mutect2, varscan2
- TPTE | c.1356G>A p.S452= (on ENST00000618007 / NM_199261.4; = p.S434= on NM_199259.4) | Splice Region (SNP) | VAF 17/86 reads (20%) | catalogued as rs768753774; called by muse, mutect2, varscan2
- TRHDE | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1386395965; called by muse, mutect2, varscan2
- TTN | c.46106C>A p.A15369E (on ENST00000591111; = p.A7945E on NM_003319.4) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | PolyPhen benign (0.3); catalogued as COSV100593054; called by muse, mutect2, varscan2
- WDR54 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs746088546; called by muse, mutect2, varscan2
- WT1 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.445); catalogued as COSV60065369; called by muse, mutect2, varscan2
- ZC3H4 | c.3686C>T p.P1229L | Missense Mutation (SNP) | VAF 41/58 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1293032665; called by muse, mutect2, varscan2
- ZFP42 | c.521A>T p.K174M | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as COSV100478993, COSV58819789; called by muse, mutect2, varscan2
- ZNF283 | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 59/81 reads (73%) | catalogued as COSV100191122; called by muse, mutect2, varscan2
- ZNF831 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 91/151 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV64038387; called by muse, mutect2, varscan2
- ABCA12 | c.6665T>G p.F2222C (on ENST00000272895 / NM_173076.3; = p.F1904C on NM_015657.3) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.428); called by muse, mutect2
- ABCC11 | c.3071A>G p.Q1024R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADAM28 | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- AKAP1 | c.2557A>C p.T853P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- AMPD1 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by mutect2, varscan2
- C5orf34 | c.1657T>C p.S553P | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC8 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by mutect2, varscan2
- CHL1 | c.1925T>G p.I642S (on ENST00000397491 / NM_001253387.1; = p.I658S on NM_006614.4) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- COL11A2 | c.2015A>C p.K672T (on ENST00000341947 / NM_080680.3; = p.K565T on NM_080679.2) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- D2HGDH | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); called by muse, mutect2
- DCLRE1A | c.1838A>G p.D613G | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by mutect2, varscan2
- DCST1 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- DNAH9 | c.3286C>A p.L1096M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DOCK10 | c.4585A>G p.N1529D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DSEL | c.2239G>T p.A747S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPB41L2 | c.816G>C p.W272C | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ERP27 | c.609A>C p.K203N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- F2R | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GBP1 | c.1532G>C p.R511T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GRIK3 | c.2561_2562dup p.Q855Sfs*31 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- GSTM5 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- HAPLN3 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HHAT | c.1360A>G p.K454E | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHA1 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IL1RAPL1 | c.958A>C p.I320L | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.68); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- KCNT2 | c.235A>T p.I79F | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIF6 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- LCMT1 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MDC1 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NCKAP1 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- NEB | c.5129T>G p.I1710S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NFIC | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NOX4 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NUP98 | c.4015A>G p.T1339A (on ENST00000359171 / NM_001365126.1; = p.T1322A on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- NVL | c.63_64dup p.T22Ifs*15 | Frame Shift Ins (INS) | VAF 9/73 reads (12%) | called by mutect2, pindel
- PREX2 | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2
- PUM1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- RECQL | c.552A>C p.L184F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- RFXAP | c.743T>C p.L248S | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RMDN2 | c.839A>C p.N280T (on ENST00000354545 / NM_001322212.2; = p.N458T on NM_144713.5) | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- RNF169 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- RSRC1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- SCUBE1 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SCYL3 | c.1672_1673dup p.Q559Pfs*21 (on ENST00000367770; = p.Q505Pfs*21 on NM_020423.7) | Frame Shift Ins (INS) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- SLC12A5 | c.143G>T p.S48I (on ENST00000454036 / NM_001134771.2; = p.S25I on NM_020708.5) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SLC13A4 | c.1282C>G p.P428A | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPATA31A1 | c.1163A>C p.N388T | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SPTB | c.5585T>C p.L1862P | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCERG1L | c.1370T>C p.F457S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THUMPD3 | c.1448T>C p.I483T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC5D | c.2626C>A p.Q876K | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- VCL | c.3379G>T p.V1127F (on ENST00000211998 / NM_014000.3; = p.V1059F on NM_003373.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- WSCD2 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ZAN | c.6595C>T p.P2199S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ABCA13 | c.6612T>G p.L2204= | Silent (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- ADGRB3 | c.3156A>G p.G1052= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- ADH1A | c.495G>A p.S165= | Silent (SNP) | VAF 39/56 reads (70%) | catalogued as rs755100175, COSV52924281; called by muse, mutect2, varscan2
- ANK2 | c.5427G>A p.A1809= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs768956474; called by muse, mutect2
- ANKS1B | c.912A>G p.Q304= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV61341940; called by mutect2, varscan2
- AUNIP | c.33C>T p.C11= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs926220223; called by muse, mutect2, varscan2
- BCLAF1 | c.847C>A p.R283= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs777984166, COSV62143723; called by mutect2, varscan2
- C8B | c.87C>A p.G29= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV64777676; called by muse, mutect2, varscan2
- CHST7 | c.306G>A p.Q102= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- DPP9 | c.651C>T p.G217= (on ENST00000598800; = p.G246= on NM_139159.5) | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as rs368915583, COSV53591384; called by muse, mutect2, varscan2
- EIF3H | c.885G>A p.P295= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs770749973, COSV52663647, COSV99411450; called by muse, mutect2, varscan2
- ERN2 | c.2298G>A p.P766= | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as rs145229386; called by muse, mutect2, varscan2
- FBXL18 | c.1989G>A p.S663= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as rs532591407; called by muse, mutect2, varscan2
- HAP1 | c.1101G>A p.S367= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs781864534; called by muse, mutect2, varscan2
- HLA-DPB1 | c.228G>A p.A76= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as rs553686794; called by muse, mutect2, varscan2
- IL17RC | c.2256G>A p.A752= (on ENST00000295981 / NM_153461.4; = p.A666= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs762979312; called by muse, mutect2, varscan2
- MED16 | c.1038C>T p.N346= | Silent (SNP) | VAF 56/85 reads (66%) | catalogued as rs374459668; called by muse, mutect2, varscan2
- NDE1 | c.12C>T p.S4= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs572790932; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- NPEPL1 | c.864G>A p.A288= | Silent (SNP) | VAF 39/208 reads (19%) | catalogued as rs757179783; called by muse, mutect2, varscan2
- OR51E1 | c.63T>A p.P21= | Silent (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- OR5T1 | c.600T>C p.S200= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100478902, COSV57301674, COSV57301917; called by muse, mutect2
- PCDH17 | c.1674G>A p.G558= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs770169677; called by muse, varscan2
- RTL3 | c.723T>G p.T241= | Silent (SNP) | VAF 38/47 reads (81%) | catalogued as COSV58185942; called by muse, mutect2, varscan2
- RTP5 | c.1707G>A p.P569= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs542496668; called by mutect2, varscan2
- TLL1 | c.843T>G p.P281= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV50282781; called by muse, mutect2, varscan2
- VANGL2 | c.1299G>A p.T433= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs756021386; called by muse, mutect2, varscan2
- ZNF644 | c.3414A>C p.S1138= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- EPHA6 | c.1895-8918G>C | Intron (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- PREX2 | c.2716-2790T>A | Intron (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
